Somatic mutation profile of tumor specimen ALCH-B39M-TTP1-A (aliquot ALCH-B39M-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B39M, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.3 years (20,925 days).
Specimen ALCH-B39M-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2eedd148-6e93-424a-8359-b8c653dacbcb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B39M-NB1-A (Blood Derived Normal), aliquot ALCH-B39M-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f7e90d6-0ad4-477c-9242-72ebc27eb53b

The open-access MAF lists 771 somatic variants for this specimen: 519 protein-altering or splice-affecting, 166 silent, 86 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 442, Silent 166, Nonsense Mutation 47, Intron 35, RNA 22, Frame Shift Del 14, 3'UTR 13, Splice Site 9, 5'Flank 7, 5'UTR 6, Splice Region 5, 3'Flank 3.

Variants (750 of 771; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 26/190 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACSL1 | c.948G>C p.L316F | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.123); catalogued as COSV55663111; called by muse, mutect2
- ACSM5 | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV59375367; called by muse, mutect2
- ADAMTS20 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 33/385 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs577775989; called by muse, mutect2
- AGTPBP1 | c.2165G>A p.R722H (on ENST00000357081 / NM_001330701.2; = p.R682H on NM_015239.2) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs951175434, COSV61276270; called by muse, mutect2
- AK5 | c.1318G>T p.V440F (on ENST00000354567 / NM_174858.3; = p.V414F on NM_012093.4) | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV60970735; called by muse, mutect2
- AMTN | c.518C>A p.P173Q | Missense Mutation (SNP) | VAF 62/453 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.748); catalogued as COSV100219662; called by muse, mutect2, varscan2
- ANKH | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 186/571 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD1110106; called by muse, mutect2, varscan2
- APBB2 | c.991A>G p.R331G (on ENST00000295974 / NM_001166050.2; = p.R332G on NM_004307.2) | Missense Mutation (SNP) | VAF 29/261 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as rs760912754; called by muse, mutect2, varscan2
- ARHGEF26 | c.2416G>T p.D806Y | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62844268; called by muse, mutect2, varscan2
- ASPM | c.6488A>G p.Y2163C | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54130685; called by muse, mutect2
- AXL | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56567403; called by muse, mutect2, varscan2
- BMP6 | c.1052G>T p.G351V | Missense Mutation (SNP) | VAF 45/321 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573617365, COSV51665855; called by muse, mutect2, varscan2
- C1orf226 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100907974; called by muse, mutect2
- CACNA1E | c.5444C>A p.T1815K | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs1032526065; called by muse, mutect2, varscan2
- CCDC82 | c.1202A>T p.Q401L | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as rs934472910; called by muse, mutect2
- CCN1 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 11/225 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs1346496644, CM148880; called by muse, mutect2
- CDH2 | c.2062C>T p.P688S | Missense Mutation (SNP) | VAF 39/365 reads (11%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.713); catalogued as COSV52295803; called by muse, mutect2, varscan2
- CHL1 | c.2598C>A p.N866K (on ENST00000397491 / NM_001253387.1; = p.N882K on NM_006614.4) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs755483886; called by muse, mutect2
- CHRD | c.1440G>A p.T480= | Splice Region (SNP) | VAF 8/48 reads (17%) | catalogued as rs1186784630; called by muse, mutect2, varscan2
- COL6A6 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV62025779; called by muse, mutect2, varscan2
- CPA5 | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV62570492; called by muse, mutect2, varscan2
- CPS1 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1432483864, COSV51809640; called by muse, mutect2
- CRCT1 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 36/237 reads (15%) | PolyPhen possibly damaging (0.619); catalogued as COSV57501600; called by mutect2, varscan2
- DCAF4L2 | c.619C>A p.Q207K | Missense Mutation (SNP) | VAF 80/371 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV60477738; called by muse, mutect2, varscan2
- DDB1 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57105869; called by muse, mutect2
- DPEP1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1267257006; called by muse, mutect2, varscan2
- EFHB | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 35/414 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.138); catalogued as COSV55551972; called by muse, mutect2
- EIF3I | c.629A>G p.N210S | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1402519965; called by muse, mutect2
- ELN | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554660123; called by muse, mutect2, varscan2
- EPHB1 | c.1519C>G p.R507G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV67656911, COSV67657380; called by muse, mutect2
- EPHB6 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 20/400 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV67418161; called by muse, mutect2
- EPSTI1 | c.949G>C p.G317R (on ENST00000398762 / NM_001330543.2; = p.G306R on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as COSV58043912; called by muse, mutect2, varscan2
- FAM135A | c.2477G>T p.S826I (on ENST00000370479 / NM_001351599.1; = p.S613I on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52052429; called by muse, mutect2, varscan2
- FAM205A | c.3908C>A p.S1303Y | Missense Mutation (SNP) | VAF 36/316 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV66490303; called by muse, mutect2, varscan2
- FAM83B | c.2690G>T p.R897L | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV60920064; called by muse, mutect2, varscan2
- FBXL7 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.207); catalogued as rs1389047293, COSV61641082, COSV61645644; called by muse, mutect2
- FLG | c.5026A>T p.S1676C | Missense Mutation (SNP) | VAF 92/483 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64236903, COSV64245756; called by muse, mutect2, varscan2
- FLNC | c.5854A>G p.M1952V | Missense Mutation (SNP) | VAF 38/243 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1373889942; called by muse, mutect2, varscan2
- FMN2 | c.3620C>A p.P1207H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.169); catalogued as COSV60420974; called by muse, mutect2, varscan2
- GAB4 | c.1595C>T p.S532F | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs768612510; called by muse, mutect2, varscan2
- GABRG1 | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 15/119 reads (13%) | catalogued as COSV54954987; called by muse, mutect2, varscan2
- GABRQ | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 28/136 reads (21%) | catalogued as COSV100941404, COSV64783731; called by muse, mutect2, varscan2
- GALR1 | c.862G>T p.A288S | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.74); catalogued as rs149816752; called by muse, mutect2
- GCN1 | c.2234C>T p.T745I | Missense Mutation (SNP) | VAF 23/340 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100325528; called by muse, mutect2
- GGPS1 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.083); catalogued as COSV51397851; called by muse, mutect2, varscan2
- GLI2 | c.2026G>T p.D676Y (on ENST00000361492 / NM_001374353.1; = p.D693Y on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58042113; called by muse, mutect2
- GLT1D1 | c.710C>T p.A237V (on ENST00000442111 / NM_001366889.1; = p.A157V on NM_144669.3) | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs773452218, COSV55886220; called by muse, mutect2, varscan2
- GLYATL1 | c.471C>A p.H157Q (on ENST00000317391 / NM_001354699.1; = p.H188Q on NM_080661.4) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.152); catalogued as rs1206493727; called by muse, mutect2
- HGF | c.1117C>T p.R373* | Nonsense Mutation (SNP) | VAF 73/452 reads (16%) | catalogued as COSV55948818; called by muse, mutect2, varscan2
- HOXB2 | c.781del p.R261Gfs*3 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs1327574793; called by mutect2, pindel, varscan2
- HYOU1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0.021); catalogued as rs1424659501, COSV68215205; called by muse, mutect2
- IL7R | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 16/207 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.059); catalogued as COSV57407515; called by muse, mutect2
- ITGA6 | c.2813G>A p.R938K (on ENST00000442250; = p.R899K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV51228433; called by muse, mutect2
- KCNA1 | c.1046C>A p.A349E | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.226); catalogued as COSV66836423, COSV66837186; called by muse, mutect2, varscan2
- KCNA5 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52906552; called by muse, mutect2, varscan2
- KCNH7 | c.2288C>T p.T763I | Missense Mutation (SNP) | VAF 26/677 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs866203323; called by muse, mutect2
- KCP | c.3757G>T p.A1253S (on ENST00000620378; = p.A1377S on NM_001366122.1) | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.037); catalogued as rs568886466; called by muse, mutect2, varscan2
- KIAA0100 | c.3976G>T p.A1326S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV101197315; called by muse, mutect2, varscan2
- KIAA1755 | c.1164G>T p.R388S | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV54076028; called by muse, mutect2, varscan2
- KIF21B | c.3835G>T p.V1279F | Missense Mutation (SNP) | VAF 14/265 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.854); catalogued as rs1282586376; called by muse, mutect2
- KLHL1 | c.1146G>T p.W382C | Missense Mutation (SNP) | VAF 75/253 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64768952; called by muse, mutect2, varscan2
- KRTAP11-1 | c.470C>A p.S157Y | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100190874; called by muse, mutect2, varscan2
- LCE2C | c.232C>A p.P78T | Missense Mutation (SNP) | VAF 44/349 reads (13%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.565); catalogued as rs767003504; called by muse, mutect2, varscan2
- LRP1B | c.9765G>T p.W3255C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as COSV67197436; called by muse, mutect2, varscan2
- LRP1B | c.9764G>T p.W3255L | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV67194773; called by muse, mutect2, varscan2
- LRRC52 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54232337, COSV99674174; called by muse, mutect2, varscan2
- LRRC66 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as rs776170857, COSV100603030, COSV58634946; called by muse, mutect2, varscan2
- LRRN1 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV60015846; called by muse, mutect2
- MGAM2 | c.3094G>T p.G1032C | Missense Mutation (SNP) | VAF 40/284 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs1303657634; called by muse, mutect2, varscan2
- MGAT5B | c.2068C>T p.R690W (on ENST00000569840 / NM_001199172.2; = p.R688W on NM_144677.3) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as rs765459462, COSV56929505; called by muse, mutect2, varscan2
- MIGA2 | c.868G>T p.E290* | Nonsense Mutation (SNP) | VAF 14/162 reads (9%) | catalogued as COSV99477842; called by muse, mutect2
- MLST8 | c.147G>T p.E49D | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV100063568; called by muse, mutect2, varscan2
- MMP9 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63433924; called by muse, mutect2, varscan2
- MRPS30 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769000170; called by muse, mutect2, varscan2
- MUC16 | c.10439del p.G3480Efs*14 | Frame Shift Del (DEL) | VAF 57/387 reads (15%) | catalogued as COSV67458733; called by mutect2, pindel, varscan2
- MUC16 | c.3578C>A p.P1193H | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV67457442; called by muse, mutect2, varscan2
- MYPN | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.057); catalogued as COSV62734015; called by muse, mutect2, varscan2
- NAGK | c.910C>A p.L304M | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99730685; called by muse, mutect2
- NALCN | c.4036C>A p.L1346M | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.137); catalogued as COSV51948891; called by muse, mutect2, varscan2
- NAV2 | c.5396C>T p.S1799F (on ENST00000396087 / NM_001244963.2; = p.S1743F on NM_145117.5) | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100215877; called by muse, mutect2
- NELL2 | c.2218G>T p.E740* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | catalogued as COSV100418415, COSV61581141; called by muse, mutect2
- NUAK2 | c.915G>T p.W305C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100904024; called by muse, mutect2, varscan2
- OPRL1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 37/288 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100401994; called by muse, mutect2, varscan2
- OR14K1 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.637); catalogued as COSV99314885; called by muse, mutect2
- OR2G3 | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV60680826, COSV60681080; called by muse, mutect2
- OR2L8 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100594020; called by muse, mutect2
- OR4K1 | c.620C>G p.S207* | Nonsense Mutation (SNP) | VAF 11/177 reads (6%) | catalogued as COSV53459364; called by muse, mutect2
- OR4Q3 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV59178752; called by muse, mutect2
- OR51B5 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV56177220; called by mutect2, varscan2
- OR51T1 | c.815G>A p.R272K | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as rs771605359; called by muse, mutect2, varscan2
- OR8A1 | c.474A>G p.I158M | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.213); catalogued as COSV99420392; called by muse, mutect2
- P2RX2 | c.207G>C p.E69D (on ENST00000343948 / NM_170683.4; = p.E47Q on NM_012226.5) | Missense Mutation (SNP) | VAF 10/161 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1161893145, COSV57691887; called by muse, mutect2
- PAX3 | c.124G>T p.G42C | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773327091; called by muse, mutect2
- PDCD10 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 35/262 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as COSV67102393; called by muse, mutect2, varscan2
- PEG3 | c.2928G>T p.E976D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99686893; called by muse, mutect2, varscan2
- PFKFB1 | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 28/165 reads (17%) | PolyPhen probably damaging (0.978); catalogued as rs1313106902; called by muse, mutect2, varscan2
- PHF20L1 | c.2939G>T p.G980V | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55188128; called by muse, mutect2, varscan2
- PIK3R1 | c.1156C>T p.R386* (on ENST00000521381 / NM_181523.3; = p.R116* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV57126203, COSV57144628; called by muse, mutect2, varscan2
- PKP2 | c.749G>T p.R250L | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as rs369332786; ClinVar: uncertain significance; called by muse, mutect2
- PLEKHA7 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 18/104 reads (17%) | catalogued as COSV63045884; called by muse, mutect2
- PPM1K | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV55798345; called by muse, mutect2, varscan2
- PPP1R3A | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 43/426 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV52890859; called by muse, mutect2, varscan2
- PRDM11 | c.1095C>G p.I365M (on ENST00000530656 / NM_001359633.1; = p.I331M on NM_001256695.1) | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.311); catalogued as COSV99771136; called by muse, mutect2
- PRDM9 | c.1252G>A p.G418R | Missense Mutation (SNP) | VAF 170/730 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as rs776940752; called by muse, mutect2, varscan2
- PRKAG2 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 103/629 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as rs121908987, CM011949; called by muse, mutect2, varscan2
- PTCHD4 | c.1278G>T p.M426I | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV59792677; called by muse, mutect2, varscan2
- PTPRQ | c.6019C>A p.L2007M (on ENST00000616559; = p.L1965M on NM_001145026.2) | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.868); catalogued as COSV57045535; called by muse, mutect2
- RGS7 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 30/534 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58531245, COSV58531779; called by muse, mutect2
- RNASE12 | c.264C>A p.C88* | Nonsense Mutation (SNP) | VAF 57/490 reads (12%) | catalogued as rs979740702; called by muse, mutect2, varscan2
- RYR2 | c.14528G>C p.R4843P | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63676917; called by muse, mutect2
- SALL4 | c.2902G>T p.V968L | Missense Mutation (SNP) | VAF 73/620 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs199529190; called by muse, mutect2, varscan2
- SCN10A | c.3619G>T p.A1207S | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs756162245; called by muse, mutect2, varscan2
- SEC16B | c.2724G>T p.K908N | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs761513538; called by muse, mutect2, varscan2
- SELP | c.2237C>T p.T746I | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.042); catalogued as rs954221578; called by muse, mutect2, varscan2
- SERPINA6 | c.164T>A p.V55E | Missense Mutation (SNP) | VAF 32/263 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as rs1359866404; called by muse, mutect2, varscan2
- SLC24A3 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as rs775903076, COSV60124519; called by muse, mutect2, varscan2
- SLC25A20 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs562426357; called by muse, varscan2
- SLC26A4 | c.445G>C p.G149R | Missense Mutation (SNP) | VAF 63/482 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1212179; called by muse, mutect2, varscan2
- SLC38A4 | c.1193T>C p.L398S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534580127; called by muse, mutect2
- SLC4A1 | c.1461C>G p.I487M | Missense Mutation (SNP) | VAF 32/272 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV52262220, COSV99293717; called by muse, mutect2, varscan2
- SLC4A10 | c.202C>A p.R68S | Missense Mutation (SNP) | VAF 22/233 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.406); catalogued as COSV55771006, COSV99765297; called by muse, mutect2
- SPRR1B | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs770728317, COSV61067745; called by muse, mutect2, varscan2
- SPTBN2 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59460690; called by muse, mutect2, varscan2
- TAC1 | c.143T>C p.F48S | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1230564121, COSV100071108; called by muse, mutect2, varscan2
- TBC1D14 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs772814515; called by muse, mutect2, varscan2
- TBX19 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 84/521 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs765043625; called by muse, mutect2, varscan2
- TEP1 | c.1582C>G p.R528G | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs540342712, COSV52990032; called by mutect2, varscan2
- TIGD2 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.351); catalogued as rs971561607; called by muse, mutect2, varscan2
- TJP1 | c.4170G>T p.Q1390H | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV62044802; called by muse, mutect2, varscan2
- TLE4 | c.857A>G p.K286R | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs766140439; called by muse, mutect2
- TNR | c.1963+1G>T p.X655_splice | Splice Site (SNP) | VAF 6/48 reads (13%) | catalogued as COSV54898935; called by mutect2, varscan2
- TOX3 | c.1674G>T p.Q558H | Missense Mutation (SNP) | VAF 33/420 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV99568261; called by muse, mutect2
- TPRX1 | c.737C>A p.P246Q | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as COSV100445957; called by muse, mutect2, varscan2
- TRIM64C | c.1283T>G p.L428R | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV73267312, COSV73267459; called by muse, mutect2
- TSHZ3 | c.1436C>G p.A479G | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV53668205; called by muse, mutect2, varscan2
- TTC21A | c.2377G>A p.G793R | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.826); catalogued as COSV57189126; called by muse, mutect2
- WDR87 | c.1037A>T p.E346V | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1168633760; called by muse, mutect2, varscan2
- WT1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100187013; called by muse, mutect2
- ZBTB18 | c.1303G>T p.E435* | Nonsense Mutation (SNP) | VAF 10/130 reads (8%) | catalogued as COSV62396343; called by muse, mutect2
- ZGRF1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.717); catalogued as rs773871051; called by muse, mutect2, varscan2
- ZIC1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 26/171 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV51552157; called by muse, mutect2, varscan2
- ZNF467 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.586); catalogued as rs766949047; called by muse, mutect2, varscan2
- ZNF556 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1164101611; called by muse, mutect2, varscan2
- ZNF804A | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100167488; called by muse, mutect2
- ZSCAN5A | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 27/189 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV104391257, COSV54231894; called by muse, mutect2, varscan2
- A2M | c.4117C>A p.R1373S | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- A2M | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.219); called by muse, mutect2
- ABCA13 | c.3191G>T p.G1064V | Missense Mutation (SNP) | VAF 40/322 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- ACOD1 | c.139A>T p.T47S | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR2A | c.1347+2T>A p.X449_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- ADA2 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADAM22 | c.212A>T p.D71V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- ADAMTS16 | c.3485G>T p.G1162V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ADAMTS5 | c.2026T>G p.Y676D | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRE2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRG3 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.084); called by muse, varscan2
- ADGRG7 | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- AGO3 | c.1273-2A>T p.X425_splice | Splice Site (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- AGXT2 | c.1124T>A p.L375Q | Missense Mutation (SNP) | VAF 147/550 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- AHNAK2 | c.15478C>T p.Q5160* | Nonsense Mutation (SNP) | VAF 5/97 reads (5%) | called by muse, mutect2
- AKAP3 | c.281C>A p.P94Q | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- AKR1B10 | c.908+8G>C | Splice Region (SNP) | VAF 29/294 reads (10%) | called by muse, mutect2, varscan2
- AKR1D1 | c.89A>T p.K30I | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ALPK2 | c.1243A>T p.S415C | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ANKRD12 | c.820G>T p.G274C | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD30B | c.253C>A p.H85N | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2
- ANKRD30B | c.255T>G p.H85Q | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.51); called by muse, mutect2
- ANKRD30BL | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- ANO2 | c.2276T>C p.F759S (on ENST00000356134 / NM_001278597.3; = p.F763S on NM_001278596.3) | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AP1M1 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 28/161 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.672); called by muse, mutect2, varscan2
- AP3B2 | c.2015A>G p.E672G | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- AP5M1 | c.779G>C p.G260A | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- ASPM | c.9712G>T p.V3238F | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- ASS1 | c.121A>T p.K41* | Nonsense Mutation (SNP) | VAF 43/342 reads (13%) | called by muse, mutect2, varscan2
- ATP2B2 | c.2744C>A p.A915D (on ENST00000352432; = p.A881D on NM_001683.5) | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ATP6V0A1 | c.2230C>T p.L744F (on ENST00000343619 / NM_001378531.1; = p.L738F on NM_005177.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATXN2L | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAM | c.1714A>T p.R572* | Nonsense Mutation (SNP) | VAF 19/106 reads (18%) | called by muse, mutect2, varscan2
- BCL11A | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BCL9L | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.305); called by mutect2, varscan2
- BHMT | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- BICDL1 | c.898A>G p.K300E | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- BPIFB3 | c.1352C>A p.P451H | Missense Mutation (SNP) | VAF 40/277 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRINP2 | c.325A>T p.S109C | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- BZW1 | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2, varscan2
- C1orf127 | c.1796T>A p.L599Q | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- C2CD4C | c.682G>T p.G228W | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C4orf54 | c.4398C>A p.D1466E | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CACNA2D3 | c.1948del p.A650Qfs*21 | Frame Shift Del (DEL) | VAF 20/221 reads (9%) | called by mutect2, pindel
- CACNG8 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAMSAP1 | c.573C>G p.F191L | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CAMSAP2 | c.3600G>T p.L1200F (on ENST00000236925 / NM_001297707.2; = p.L1189F on NM_203459.3) | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CASKIN1 | c.384T>G p.Y128* | Nonsense Mutation (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- CCDC105 | c.1390C>G p.R464G | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC141 | c.3961G>A p.E1321K | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.211); called by muse, mutect2
- CCDC168 | c.18676G>T p.E6226* | Nonsense Mutation (SNP) | VAF 24/461 reads (5%) | called by muse, mutect2
- CCDC175 | c.954-1G>A p.X318_splice | Splice Site (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- CD200R1 | c.544C>A p.P182T (on ENST00000471858 / NM_170780.3; = p.P205T on NM_138806.4) | Missense Mutation (SNP) | VAF 51/408 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD2AP | c.1513T>G p.F505V | Missense Mutation (SNP) | VAF 70/334 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDC73 | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 22/416 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CDH2 | c.458A>T p.H153L | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDH23 | c.1623G>C p.E541D | Missense Mutation (SNP) | VAF 32/311 reads (10%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CENPT | c.1457+1G>T p.X486_splice | Splice Site (SNP) | VAF 32/262 reads (12%) | called by muse, mutect2, varscan2
- CFHR2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 33/507 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CGN | c.2774C>T p.S925F | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.436); called by muse, mutect2
- CGREF1 | c.447C>A p.H149Q | Missense Mutation (SNP) | VAF 51/316 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- CHRM3 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 18/353 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2
- CHRNA1 | c.841C>G p.P281A (on ENST00000261007 / NM_001039523.3; = p.P256A on NM_000079.4) | Missense Mutation (SNP) | VAF 26/334 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2
- CIT | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CLMP | c.754G>T p.V252L | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2
- COBL | c.832A>T p.T278S | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- COL11A1 | c.2044-1G>T p.X682_splice | Splice Site (SNP) | VAF 37/442 reads (8%) | called by muse, mutect2
- COL3A1 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 66/433 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COL4A6 | c.1307G>A p.G436D | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL5A2 | c.3907C>A p.H1303N | Missense Mutation (SNP) | VAF 30/459 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2
- COL6A5 | c.6144_6145delinsA p.F2049Sfs*4 (on ENST00000312481; = p.F2045Sfs*4 on NM_153264.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/143 reads (11%) | called by pindel, varscan2*
- COPE | c.708G>T p.E236D | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.415); called by mutect2, varscan2
- CPA4 | c.52C>A p.Q18K | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CPB1 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPZ | c.1604C>A p.A535D (on ENST00000360986 / NM_001014447.3; = p.A524D on NM_003652.3) | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CRACD | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 16/150 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- CSMD2 | c.10164G>T p.L3388= | Splice Region (SNP) | VAF 23/170 reads (14%) | called by muse, mutect2, varscan2
- CSPG4 | c.6685A>T p.M2229L | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CTAGE6 | c.1260A>T p.E420D | Missense Mutation (SNP) | VAF 105/1587 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CTAGE6 | c.1259A>T p.E420V | Missense Mutation (SNP) | VAF 105/1594 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2
- CTNNA2 | c.783del p.S262Rfs*31 | Frame Shift Del (DEL) | VAF 36/299 reads (12%) | called by mutect2, pindel, varscan2
- DBX2 | c.856C>A p.H286N | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.15); called by muse, mutect2
- DCAF1 | c.818G>T p.G273V | Missense Mutation (SNP) | VAF 64/508 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCDC2 | c.825G>C p.K275N | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- DCDC2C | c.786T>G p.D262E | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.045); called by muse, mutect2
- DDX42 | c.871A>G p.R291G | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DEFB132 | c.238A>G p.R80G | Missense Mutation (SNP) | VAF 57/369 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- DISP3 | c.812C>A p.A271E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- DLG5 | c.3571A>T p.I1191F | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- DLST | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- DOP1B | c.3625A>G p.R1209G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DPF3 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 31/244 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- DTHD1 | c.1885C>A p.P629T (on ENST00000456874; = p.P464T on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- E2F2 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- EDA | c.38C>A p.P13H | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- EDAR | c.467C>A p.S156Y | Missense Mutation (SNP) | VAF 90/588 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- EHBP1 | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2
- EID3 | c.31_32del p.G11Lfs*22 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel*
- EPHA1 | c.1559C>T p.T520I | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EZHIP | c.868C>A p.R290S | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- F5 | c.6365G>C p.W2122S | Missense Mutation (SNP) | VAF 59/327 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM171B | c.1801A>G p.R601G | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- FAM47A | c.1738A>C p.I580L | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM47A | c.1604C>A p.P535H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- FAM9C | c.56T>G p.L19R | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- FBXO33 | c.409C>T p.R137* | Nonsense Mutation (SNP) | VAF 16/221 reads (7%) | called by muse, mutect2
- FCGBP | c.11279G>T p.R3760L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- FLG | c.5453G>T p.G1818V | Missense Mutation (SNP) | VAF 43/486 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- FLI1 | c.185T>A p.V62E | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.556); called by muse, mutect2
- FLOT2 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 20/123 reads (16%) | called by muse, mutect2, varscan2
- FLRT2 | c.112A>T p.S38C | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- FLT1 | c.2606C>T p.A869V | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FMO1 | c.1582T>G p.F528V | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- FMO3 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FNDC7 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); called by muse, mutect2
- FOXL1 | c.464A>T p.K155M | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2
- FRMD1 | c.772G>T p.D258Y | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.7762A>G p.K2588E | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); called by mutect2, varscan2
- FYB2 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 15/377 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.221); called by muse, mutect2
- G6PC2 | c.311C>A p.T104K | Missense Mutation (SNP) | VAF 64/444 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- GAS7 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- GCGR | c.801C>A p.Y267* | Nonsense Mutation (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- GOLGA5 | c.946A>T p.S316C | Missense Mutation (SNP) | VAF 35/319 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- GPAM | c.1943G>T p.G648V | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPD1 | c.440T>A p.L147Q | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GPLD1 | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR158 | c.3535C>A p.P1179T | Missense Mutation (SNP) | VAF 47/413 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GPRASP1 | c.2480G>C p.G827A | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- GPX5 | c.17G>T p.R6M | Missense Mutation (SNP) | VAF 39/176 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- GRM1 | c.1009G>T p.G337* | Nonsense Mutation (SNP) | VAF 96/411 reads (23%) | called by muse, mutect2, varscan2
- GRM8 | c.35del p.P12Lfs*6 | Frame Shift Del (DEL) | VAF 16/112 reads (14%) | called by mutect2, pindel, varscan2
- HCLS1 | c.1109C>A p.P370H | Missense Mutation (SNP) | VAF 56/496 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- HEPH | c.3094del p.V1032Wfs*12 (on ENST00000343002; = p.V765Wfs*12 on NM_014799.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 38/167 reads (23%) | called by mutect2, pindel, varscan2
- HHIPL2 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.06); called by muse, mutect2
- HMCN1 | c.13083A>C p.E4361D | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.992); called by muse, mutect2
- HMG20A | c.764A>T p.K255M | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- HOXB1 | c.157T>A p.S53T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HSD17B11 | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- HSPBAP1 | c.76A>T p.K26* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | called by muse, mutect2, varscan2
- IGFN1 | c.549C>A p.C183* | Nonsense Mutation (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- IGLV4-3 | c.316G>T p.E106* | Nonsense Mutation (SNP) | VAF 31/233 reads (13%) | called by muse, mutect2, varscan2
- IGSF3 | c.3404C>G p.P1135R (on ENST00000369486 / NM_001007237.3; = p.P1155R on NM_001542.4) | Missense Mutation (SNP) | VAF 38/327 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL22RA2 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); called by muse, varscan2
- INO80 | c.3932A>C p.E1311A | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IQGAP3 | c.2327A>T p.Q776L | Missense Mutation (SNP) | VAF 57/303 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IRX2 | c.1331G>T p.R444L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ITGAD | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- ITGAD | c.3136C>A p.L1046I | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); called by muse, mutect2
- ITGAL | c.2559G>T p.R853S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- ITGAM | c.350C>A p.T117K | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- ITGAX | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- JPH2 | c.967C>A p.R323S | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KATNAL2 | c.572G>T p.G191V (on ENST00000356157 / NM_001353899.1; = p.G119V on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- KCNA1 | c.696C>G p.F232L | Missense Mutation (SNP) | VAF 63/462 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNG1 | c.592G>T p.G198C | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNH3 | c.3043C>A p.P1015T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- KCNT1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- KCNT1 | c.2078C>A p.P693H (on ENST00000488444; = p.P712H on NM_020822.3) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- KIAA1614 | c.3412C>A p.R1138S | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIRREL1 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 35/255 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KLK1 | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT5 | c.611A>T p.Q204L | Missense Mutation (SNP) | VAF 98/743 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KRTAP1-5 | c.361C>A p.P121T | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAMA1 | c.6072C>A p.S2024R | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMB1 | c.2005C>A p.P669T | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- LAMC3 | c.2699G>T p.R900L | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.78); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LCE3D | c.19C>A p.Q7K | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- LEPR | c.3327A>T p.L1109F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LOXHD1 | c.4920C>A p.D1640E | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- LRP2 | c.9159G>T p.E3053D | Missense Mutation (SNP) | VAF 88/577 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- LRRC43 | c.1053A>T p.E351D | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LTBP1 | c.3316G>A p.G1106R (on ENST00000404816 / NM_206943.4; = p.G780R on NM_000627.4) | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.548); called by muse, mutect2
- MAGEB6B | c.883A>G p.I295V | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP2K3 | c.549G>C p.K183N (on ENST00000342679 / NM_145109.3; = p.K154N on NM_002756.4) | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.022); called by muse, mutect2
- MARCHF1 | c.259G>T p.G87W (on ENST00000274056; = p.G70W on NM_017923.4) | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MAST3 | c.3880G>T p.E1294* | Nonsense Mutation (SNP) | VAF 44/277 reads (16%) | called by muse, mutect2, varscan2
- MEGF8 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- MGAT5B | c.2293G>C p.A765P (on ENST00000569840 / NM_001199172.2; = p.A763P on NM_144677.3) | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MLXIPL | c.1546A>G p.S516G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MMD2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 13/124 reads (10%) | called by muse, mutect2, varscan2
- MMS22L | c.3230A>G p.Y1077C | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MORC3 | c.1586A>T p.Q529L | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2
- MTIF2 | c.928G>T p.V310L | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.038); called by muse, mutect2
- MUC12 | c.14582C>G p.P4861R (on ENST00000379442; = p.P4718R on NM_001164462.1) | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2, varscan2
- MUC16 | c.41459G>T p.R13820M | Missense Mutation (SNP) | VAF 55/317 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- MUC16 | c.11771G>T p.W3924L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.11212T>A p.W3738R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MUC16 | c.9131C>G p.S3044C | Missense Mutation (SNP) | VAF 24/202 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- MYBPC1 | c.1894G>T p.G632* (on ENST00000550270 / NM_206820.2; = p.G657* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 16/229 reads (7%) | called by muse, mutect2
- MYEF2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 59/334 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYH13 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 31/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MYH2 | c.5335C>T p.Q1779* | Nonsense Mutation (SNP) | VAF 98/679 reads (14%) | called by muse, mutect2, varscan2
- NACAD | c.3313G>T p.D1105Y | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NEBL | c.2007G>T p.M669I | Missense Mutation (SNP) | VAF 61/521 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NECAB1 | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 23/134 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NEK10 | c.1999G>T p.D667Y | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.382); called by muse, mutect2
- NEURL4 | c.3953-1G>T p.X1318_splice | Splice Site (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- NEUROD4 | c.821A>G p.E274G | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- NEXMIF | c.4465G>T p.D1489Y | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- NF1 | c.1061dup p.N355Efs*5 | Frame Shift Ins (INS) | VAF 54/254 reads (21%) | called by mutect2, pindel, varscan2
- NLRP11 | c.708C>G p.F236L | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- NLRP3 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 66/402 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NLRP3 | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 80/1050 reads (8%) | called by muse, mutect2
- NOD2 | c.958C>A p.Q320K | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.051); called by muse, mutect2
- NPAS1 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NPY5R | c.964C>A p.Q322K | Missense Mutation (SNP) | VAF 28/286 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- NR1H2 | c.676A>T p.M226L | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUP214 | c.2332G>T p.G778C | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUP214 | c.2333G>T p.G778V | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NXF3 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR11H6 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 23/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OR13F1 | c.210C>A p.D70E | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR13J1 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 20/211 reads (9%) | called by muse, mutect2, varscan2
- OR14K1 | c.757G>C p.G253R | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- OR2G2 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.964); called by muse, mutect2
- OR2T4 | c.16T>A p.W6R | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.099); called by muse, mutect2
- OR2T4 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 42/665 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2
- OR4D2 | c.294G>T p.M98I | Missense Mutation (SNP) | VAF 93/705 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- OR52E8 | c.601_602insC p.N201Tfs*3 | Frame Shift Ins (INS) | VAF 25/161 reads (16%) | called by mutect2, pindel, varscan2
- OR52N1 | c.335T>G p.M112R | Missense Mutation (SNP) | VAF 32/278 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- OR5B17 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.149); called by muse, mutect2
- OR5H1 | c.703A>T p.R235W | Missense Mutation (SNP) | VAF 48/370 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR6B1 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- OVCH1 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P2RX7 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 24/190 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- PACSIN1 | c.328C>A p.L110M | Missense Mutation (SNP) | VAF 109/456 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PAXIP1 | c.2442G>C p.W814C | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH19 | c.1886C>A p.T629N | Missense Mutation (SNP) | VAF 83/325 reads (26%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PCDHA1 | c.1909C>G p.L637V | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- PCDHB10 | c.2282C>A p.P761H | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- PCDHB5 | c.1830G>T p.E610D | Missense Mutation (SNP) | VAF 76/462 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- PCSK5 | c.2989A>T p.S997C | Missense Mutation (SNP) | VAF 47/407 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PDIA5 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PFKFB4 | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 17/108 reads (16%) | called by muse, mutect2, varscan2
- PHF20L1 | c.2938G>A p.G980R | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHKA1 | c.1444A>G p.I482V | Missense Mutation (SNP) | VAF 83/272 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- PIGC | c.668G>T p.C223F | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PIP4K2A | c.71T>G p.V24G | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PKD1L2 | c.1727T>A p.F576Y | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2
- PLCH1 | c.1271G>T p.G424V (on ENST00000340059 / NM_001130960.2; = p.G436V on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/279 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); called by muse, mutect2
- PLEC | c.13402C>T p.P4468S (on ENST00000322810 / NM_201380.4; = p.P4358S on NM_000445.5) | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- POM121L2 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 63/289 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- POTEC | c.407G>T p.R136L | Missense Mutation (SNP) | VAF 89/672 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- POTEC | c.161T>C p.M54T | Missense Mutation (SNP) | VAF 51/334 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- PPP1R13B | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- PRAMEF17 | c.217C>G p.P73A | Missense Mutation (SNP) | VAF 32/491 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2
- PRAMEF18 | c.285C>T p.P95= | Splice Region (SNP) | VAF 20/704 reads (3%) | called by muse, mutect2
- PRDM12 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 44/230 reads (19%) | called by muse, mutect2, varscan2
- PRDM8 | c.1716G>T p.Q572H | Missense Mutation (SNP) | VAF 48/284 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKDC | c.1175G>C p.C392S | Missense Mutation (SNP) | VAF 34/234 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- PRR23A | c.111del p.E38Nfs*23 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- PRR23B | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PSG9 | c.988+1G>T p.X330_splice | Splice Site (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- PTCHD1 | c.124A>T p.S42C | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PTGS1 | c.1123C>A p.R375S | Missense Mutation (SNP) | VAF 30/310 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- PTPN14 | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 12/141 reads (9%) | called by muse, mutect2
- PTPRQ | c.5647A>T p.I1883F (on ENST00000616559; = p.I1841F on NM_001145026.2) | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PYHIN1 | c.1280C>A p.A427D | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- PZP | c.834C>A p.D278E | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- RALGAPA2 | c.2371A>T p.S791C | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- RAPGEF6 | c.3650A>T p.E1217V | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); called by muse, mutect2, varscan2
- RASL12 | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- RASSF2 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- RB1 | c.1325del p.G442Dfs*15 | Frame Shift Del (DEL) | VAF 42/326 reads (13%) | called by mutect2, pindel, varscan2
- RBM12B | c.955A>G p.K319E | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- RGS7 | c.1061A>T p.E354V | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RGS7 | c.231G>T p.E77D | Missense Mutation (SNP) | VAF 28/432 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); called by muse, mutect2
- RIPK4 | c.1027A>T p.K343* (on ENST00000352483; = p.K295* on NM_020639.3) | Nonsense Mutation (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- RIPOR1 | c.1445G>C p.S482T (on ENST00000379312 / NM_001193522.2; = p.S478T on NM_024519.4) | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- RNF43 | c.943A>G p.N315D | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- RNFT2 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ROBO1 | c.3443G>T p.G1148V | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.082); called by muse, mutect2
- ROBO2 | c.282del p.I95Sfs*26 | Frame Shift Del (DEL) | VAF 48/329 reads (15%) | called by mutect2, pindel, varscan2
- RTL1 | c.4005G>T p.W1335C | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.187); called by muse, varscan2
- RYR1 | c.5369G>T p.G1790V | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- RYR2 | c.7141A>C p.T2381P | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.51); called by muse, mutect2
- SCN10A | c.1120A>T p.M374L | Missense Mutation (SNP) | VAF 30/319 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2
- SEC61A2 | c.1361T>C p.I454T | Missense Mutation (SNP) | VAF 39/288 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SELL | c.368A>T p.E123V (on ENST00000650983; = p.E110V on NM_000655.5) | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SEMA3F | c.1703G>T p.W568L | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA5A | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 62/242 reads (26%) | called by muse, mutect2, varscan2
- SERPINB4 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 39/205 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- SH3RF1 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 52/340 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SHANK2 | c.3251G>T p.G1084V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIGLEC12 | c.1141A>T p.T381S (on ENST00000291707 / NM_053003.4; = p.T263S on NM_033329.2) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.18); called by muse, mutect2
- SIPA1L1 | c.2583G>T p.W861C | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIPA1L2 | c.2821-1G>A p.X941_splice | Splice Site (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- SIPA1L3 | c.445G>A p.V149M | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- SIRPA | c.463G>T p.G155C | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- SIRT1 | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 14/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SLC27A6 | c.1457G>T p.W486L | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC2A12 | c.52del p.T18Qfs*55 | Frame Shift Del (DEL) | VAF 41/212 reads (19%) | called by mutect2, pindel, varscan2
- SLC35C1 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 28/428 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2
- SLC38A10 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC38A5 | c.205C>A p.L69M | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC6A17 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC8A1 | c.2312C>A p.P771H | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC8B1 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SLCO1C1 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLITRK6 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- SMCHD1 | c.1521T>A p.N507K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SNX22 | c.391A>G p.S131G | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.035); called by muse, mutect2
- SPEG | c.4931G>C p.R1644P | Missense Mutation (SNP) | VAF 17/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SPG11 | c.403A>T p.R135W | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SPIDR | c.2692A>C p.I898L | Missense Mutation (SNP) | VAF 114/454 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPTA1 | c.6530+3G>T | Splice Region (SNP) | VAF 34/506 reads (7%) | called by muse, mutect2
- SRL | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 26/226 reads (12%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, varscan2
- STAB1 | c.5492C>A p.T1831K | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.204); called by muse, mutect2
- STON2 | c.2395T>G p.F799V (on ENST00000649389 / NM_001366849.2; = p.F742V on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2
- STXBP5 | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- SVEP1 | c.7306G>T p.V2436F | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- SWT1 | c.772A>C p.N258H | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- SYNPO2 | c.3052A>T p.N1018Y | Missense Mutation (SNP) | VAF 34/246 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- SYT16 | c.1729T>A p.F577I | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TANGO6 | c.247T>A p.W83R | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TAS2R20 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBX22 | c.1425T>A p.Y475* | Nonsense Mutation (SNP) | VAF 101/355 reads (28%) | called by muse, mutect2, varscan2
- TCHH | c.4241G>A p.R1414K | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.938); called by muse, mutect2
- TDRD12 | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- TENM3 | c.6543C>G p.I2181M | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2
- TENT5D | c.720C>A p.C240* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- TEX10 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
- TEX55 | c.617C>A p.T206N | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2
- TGFBR3 | c.989G>T p.W330L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIAM1 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.014); called by muse, mutect2
- TJP1 | c.4485G>T p.Q1495H | Missense Mutation (SNP) | VAF 35/264 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TLL1 | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM121B | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 46/370 reads (12%) | called by muse, mutect2, varscan2
- TMEM132B | c.1742C>T p.P581L | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- TMEM132C | c.1614C>A p.S538R | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- TMEM132C | c.2810C>A p.A937D | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM185A | c.476G>A p.R159K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM236 | c.44T>A p.L15Q | Missense Mutation (SNP) | VAF 95/794 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TMPRSS11F | c.122del p.I41Kfs*38 | Frame Shift Del (DEL) | VAF 14/103 reads (14%) | called by mutect2, varscan2
- TMPRSS9 | c.881C>A p.A294E (on ENST00000648592; = p.A260E on NM_182973.2) | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2
- TNR | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 11/145 reads (8%) | called by muse, mutect2
- TOMM70 | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TPX2 | c.1348A>T p.T450S | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRAV30 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- TRBV4-1 | c.259T>C p.C87R | Missense Mutation (SNP) | VAF 25/234 reads (11%) | SIFT tolerated (0.54); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- TRIM49B | c.105C>G p.C35W | Missense Mutation (SNP) | VAF 67/597 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTLL6 | c.638G>T p.R213M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.44064T>G p.Y14688* (on ENST00000591111; = p.Y7264* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.33552C>A p.S11184R (on ENST00000591111; = p.S10257R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/439 reads (5%) | PolyPhen benign (0); called by muse, mutect2
- UBE2J1 | c.149A>T p.D50V | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- UBE3C | c.1450A>G p.R484G | Missense Mutation (SNP) | VAF 58/387 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UBN2 | c.1419A>T p.E473D | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- UNC13A | c.2428G>T p.E810* | Nonsense Mutation (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- UNC5C | c.1994G>T p.S665I | Missense Mutation (SNP) | VAF 47/491 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); called by muse, mutect2
- UNC79 | c.5739G>T p.R1913S (on ENST00000393151 / NM_001346218.2; = p.R1736S on NM_020818.5) | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- UNC80 | c.3502G>A p.G1168S | Missense Mutation (SNP) | VAF 31/233 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VAX1 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- VIPR2 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VWA3A | c.319G>C p.A107P | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2
- WASHC2C | c.2462A>C p.Q821P | Missense Mutation (SNP) | VAF 34/362 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- WDFY3 | c.966A>T p.Q322H | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- WDR47 | c.2629A>T p.K877* (on ENST00000369962 / NM_001142551.2; = p.K878* on NM_014969.5) | Nonsense Mutation (SNP) | VAF 29/193 reads (15%) | called by muse, mutect2, varscan2
- WDR91 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT16 | c.664del p.R222Afs*11 (on ENST00000222462 / NM_057168.2; = p.R212Afs*11 on NM_016087.2) | Frame Shift Del (DEL) | VAF 17/89 reads (19%) | called by mutect2, pindel, varscan2
- WNT2 | c.987C>A p.H329Q | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- WNT9B | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- XIRP2 | c.5788C>A p.L1930M (on ENST00000628543; = p.L2105M on NM_152381.6) | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); called by muse, mutect2
- ZBTB3 | c.1415C>G p.A472G | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ZC3H12B | c.231C>A p.H77Q | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZDBF2 | c.1358A>T p.D453V | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ZIC3 | c.1355C>A p.T452N | Missense Mutation (SNP) | VAF 55/234 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF133 | c.697C>T p.Q233* (on ENST00000316358 / NM_001352454.2; = p.Q232* on NM_003434.7 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- ZNF155 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 42/346 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF215 | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 26/216 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, varscan2
- ZNF33A | c.43A>G p.K15E | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- ZNF705G | c.407T>C p.L136S | Missense Mutation (SNP) | VAF 48/584 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); called by muse, mutect2
- ZNF709 | c.253C>G p.Q85E | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ZSCAN25 | c.988G>T p.G330C | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ABCA2 | c.3042C>G p.P1014= (on ENST00000614293; = p.P984= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- ABCG4 | c.285G>T p.R95= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- AC026786.1 | c.495G>T p.G165= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- ACSM4 | c.189C>A p.S63= | Silent (SNP) | VAF 20/244 reads (8%) | catalogued as COSV68067839; called by muse, mutect2
- ACTA1 | c.54G>T p.L18= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- ADAM7 | c.375G>T p.T125= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV51543778; called by muse, mutect2, varscan2
- ADAMTS12 | c.4686C>T p.T1562= | Silent (SNP) | VAF 58/528 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS19 | c.822C>T p.H274= | Silent (SNP) | VAF 20/179 reads (11%) | catalogued as COSV50796218; called by muse, mutect2, varscan2
- ADAMTS6 | c.3006G>A p.E1002= | Silent (SNP) | VAF 34/326 reads (10%) | catalogued as COSV58684022; called by muse, mutect2, varscan2
- ADARB1 | c.318G>C p.A106= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV62347759; called by muse, mutect2, varscan2
- AGPAT5 | c.1062A>G p.L354= | Silent (SNP) | VAF 19/175 reads (11%) | called by muse, mutect2, varscan2
- AHNAK2 | c.9774G>A p.P3258= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as rs533365075; called by muse, mutect2, varscan2
- ALMS1 | c.2088A>T p.S696= | Silent (SNP) | VAF 23/403 reads (6%) | catalogued as rs952574608; called by muse, mutect2
- AMY2A | c.84T>C p.I28= | Silent (SNP) | VAF 37/698 reads (5%) | catalogued as rs369252607; called by muse, mutect2
- ANKRD62 | c.1551G>A p.R517= | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- ARGLU1 | c.9G>T p.R3= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as rs780912770; called by muse, mutect2, varscan2
- ARHGAP18 | c.1452G>T p.P484= | Silent (SNP) | VAF 57/309 reads (18%) | catalogued as COSV63763323; called by muse, mutect2, varscan2
- ARHGEF35 | c.1152G>T p.G384= | Silent (SNP) | VAF 52/218 reads (24%) | called by muse, mutect2, varscan2
- ARMC12 | c.480C>T p.T160= (on ENST00000373866 / NM_001286574.2; = p.T187= on NM_145028.5) | Silent (SNP) | VAF 55/181 reads (30%) | catalogued as COSV55359141; called by muse, mutect2, varscan2
- BBS5 | c.73A>C p.R25= | Silent (SNP) | VAF 30/221 reads (14%) | called by muse, mutect2, varscan2
- BDNF | c.420G>A p.V140= | Silent (SNP) | VAF 54/426 reads (13%) | catalogued as rs1329236636; called by muse, mutect2, varscan2
- BICRA | c.2706G>T p.T902= | Silent (SNP) | VAF 25/159 reads (16%) | catalogued as COSV101194438; called by muse, mutect2, varscan2
- BPIFB3 | c.90G>T p.T30= | Silent (SNP) | VAF 26/221 reads (12%) | called by muse, mutect2, varscan2
- C1orf226 | c.75C>T p.P25= | Silent (SNP) | VAF 47/253 reads (19%) | catalogued as rs560108919; called by muse, mutect2, varscan2
- C20orf203 | c.435G>T p.V145= | Silent (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- C5AR2 | c.696G>T p.R232= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as COSV57255516; called by muse, mutect2, varscan2
- CALHM4 | c.741C>A p.R247= (on ENST00000368596 / NM_001366078.1; = p.R61= on NM_153036.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/199 reads (22%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.3081T>C p.T1027= (on ENST00000236925 / NM_001297707.2; = p.T1016= on NM_203459.3) | Silent (SNP) | VAF 14/194 reads (7%) | called by muse, mutect2
- CAMTA1 | c.3498G>T p.L1166= | Silent (SNP) | VAF 32/454 reads (7%) | called by muse, mutect2
- CD7 | c.72G>T p.L24= | Silent (SNP) | VAF 26/228 reads (11%) | called by muse, mutect2, varscan2
- CD8A | c.18C>A p.T6= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- CDR2 | c.354G>T p.T118= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as COSV99193566; called by muse, mutect2, varscan2
- CLIP3 | c.1527C>A p.P509= | Silent (SNP) | VAF 44/328 reads (13%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1512G>A p.Q504= | Silent (SNP) | VAF 14/117 reads (12%) | called by muse, mutect2, varscan2
- COLEC12 | c.1440T>A p.P480= | Silent (SNP) | VAF 30/189 reads (16%) | called by muse, mutect2, varscan2
- CREBBP | c.1083G>T p.L361= | Silent (SNP) | VAF 68/535 reads (13%) | called by muse, mutect2, varscan2
- CRX | c.564C>T p.S188= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs148622001; called by muse, mutect2
- CTSF | c.504C>G p.S168= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as COSV100074225; called by muse, mutect2
- CUBN | c.8814A>G p.K2938= | Silent (SNP) | VAF 49/426 reads (12%) | called by muse, mutect2, varscan2
- CYP2A7 | c.459G>A p.S153= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as rs747745785, COSV99394634; called by muse, mutect2, varscan2
- DHX34 | c.2799T>C p.S933= | Silent (SNP) | VAF 30/142 reads (21%) | called by muse, varscan2
- DIAPH3 | c.2772G>A p.Q924= (on ENST00000400324 / NM_001042517.2; = p.Q661= on NM_030932.3) | Silent (SNP) | VAF 62/226 reads (27%) | called by muse, mutect2, varscan2
- DIRAS2 | c.423C>T p.R141= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- DLGAP2 | c.1119G>C p.T373= | Silent (SNP) | VAF 11/163 reads (7%) | catalogued as rs774894552, COSV101421136; called by muse, mutect2
- DNAI3 | c.270C>A p.V90= | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- DPY19L2 | c.1428C>A p.T476= | Silent (SNP) | VAF 14/186 reads (8%) | called by muse, mutect2
- DSEL | c.645G>A p.E215= | Silent (SNP) | VAF 62/375 reads (17%) | catalogued as COSV59491855; called by muse, mutect2, varscan2
- EARS2 | c.732G>T p.V244= | Silent (SNP) | VAF 14/154 reads (9%) | called by muse, mutect2
- EBLN1 | c.999T>A p.P333= | Silent (SNP) | VAF 24/191 reads (13%) | called by muse, mutect2, varscan2
- EOMES | c.1293A>C p.A431= | Silent (SNP) | VAF 51/429 reads (12%) | catalogued as rs755427054, COSV55412409; called by muse, mutect2, varscan2
- EP300 | c.2610A>T p.P870= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- EPS8L3 | c.903G>T p.L301= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- ERBB2 | c.1134G>C p.P378= | Silent (SNP) | VAF 26/173 reads (15%) | called by muse, mutect2, varscan2
- F5 | c.594A>G p.L198= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- FDXR | c.1299C>T p.G433= (on ENST00000293195 / NM_024417.5; = p.G439= on NM_004110.6) | Silent (SNP) | VAF 46/141 reads (33%) | called by muse, mutect2, varscan2
- FEZF1 | c.171C>A p.P57= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- FGB | c.651A>T p.S217= | Silent (SNP) | VAF 38/387 reads (10%) | called by muse, mutect2, varscan2
- FLII | c.1980G>T p.R660= | Silent (SNP) | VAF 40/280 reads (14%) | catalogued as COSV57496752; called by muse, mutect2, varscan2
- FLOT2 | c.876C>T p.A292= | Silent (SNP) | VAF 20/130 reads (15%) | catalogued as rs574662905; called by muse, mutect2, varscan2
- FNDC3B | c.2601C>T p.L867= | Silent (SNP) | VAF 58/461 reads (13%) | called by muse, mutect2, varscan2
- GALNT13 | c.555C>A p.R185= | Silent (SNP) | VAF 18/492 reads (4%) | called by muse, mutect2
- GALR1 | c.384G>T p.A128= | Silent (SNP) | VAF 43/223 reads (19%) | catalogued as COSV55316630; called by muse, mutect2, varscan2
- GBP6 | c.1572G>A p.K524= | Silent (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- GLT6D1 | c.165C>T p.V55= | Silent (SNP) | VAF 32/230 reads (14%) | catalogued as rs779463976; called by muse, mutect2, varscan2
- GPR139 | c.546C>A p.V182= | Silent (SNP) | VAF 9/103 reads (9%) | catalogued as rs769710864; called by muse, mutect2
- GRIA1 | c.2629C>A p.R877= | Silent (SNP) | VAF 34/368 reads (9%) | catalogued as COSV53623012; called by muse, mutect2
- GSTA1 | c.471C>T p.D157= | Silent (SNP) | VAF 78/427 reads (18%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.390C>T p.F130= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as COSV56477660; called by muse, mutect2, varscan2
- GUCY1B1 | c.1221G>T p.R407= | Silent (SNP) | VAF 37/257 reads (14%) | called by muse, mutect2, varscan2
- HEATR6 | c.2466G>T p.L822= | Silent (SNP) | VAF 67/506 reads (13%) | called by muse, mutect2, varscan2
- HYDIN | c.7500C>A p.V2500= | Silent (SNP) | VAF 16/167 reads (10%) | called by muse, mutect2
- IL7R | c.1161C>A p.S387= | Silent (SNP) | VAF 18/208 reads (9%) | catalogued as COSV57412004; called by muse, mutect2
- KALRN | c.564C>A p.L188= | Silent (SNP) | VAF 49/340 reads (14%) | called by muse, mutect2, varscan2
- KCNH8 | c.2187C>G p.P729= | Silent (SNP) | VAF 48/420 reads (11%) | catalogued as rs761445247; called by muse, mutect2, varscan2
- KCNIP1 | c.27A>G p.S9= | Silent (SNP) | VAF 29/219 reads (13%) | called by muse, mutect2, varscan2
- KCNK13 | c.807C>G p.V269= | Silent (SNP) | VAF 49/479 reads (10%) | catalogued as rs1006517561, COSV56413285; called by muse, mutect2, varscan2
- KIAA2012 | c.36G>C p.G12= | Silent (SNP) | VAF 12/156 reads (8%) | called by muse, mutect2
- KRT9 | c.1359C>A p.T453= | Silent (SNP) | VAF 35/203 reads (17%) | catalogued as COSV99879289; called by muse, mutect2, varscan2
- LAIR1 | c.501C>T p.L167= | Silent (SNP) | VAF 13/294 reads (4%) | catalogued as rs1206975990, COSV100479575; called by muse, mutect2
- LCT | c.912A>T p.I304= | Silent (SNP) | VAF 21/274 reads (8%) | called by muse, mutect2
- LGI2 | c.840T>C p.C280= | Silent (SNP) | VAF 7/43 reads (16%) | called by muse, mutect2, varscan2
- LMBR1L | c.789G>T p.L263= | Silent (SNP) | VAF 39/228 reads (17%) | called by muse, mutect2, varscan2
- LRIT2 | c.516G>T p.L172= | Silent (SNP) | VAF 36/192 reads (19%) | catalogued as rs1564672491; called by muse, mutect2, varscan2
- LTB | c.612C>T p.S204= | Silent (SNP) | VAF 44/253 reads (17%) | called by muse, mutect2, varscan2
- LTBP1 | c.4638G>T p.T1546= (on ENST00000404816 / NM_206943.4; = p.T1220= on NM_000627.4) | Silent (SNP) | VAF 50/363 reads (14%) | catalogued as rs147747384; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.540G>A p.L180= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- MAB21L3 | c.957G>A p.V319= | Silent (SNP) | VAF 32/532 reads (6%) | called by muse, mutect2
- MARCHF11 | c.1005G>A p.R335= | Silent (SNP) | VAF 56/517 reads (11%) | catalogued as COSV100198307; called by muse, mutect2, varscan2
- MGAM | c.2355C>T p.V785= | Silent (SNP) | VAF 34/327 reads (10%) | called by muse, mutect2, varscan2
- MMP20 | c.894C>A p.S298= | Silent (SNP) | VAF 86/646 reads (13%) | called by muse, mutect2, varscan2
- MOCOS | c.570A>T p.P190= | Silent (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- MPDZ | c.2847A>T p.T949= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as rs751100435; called by muse, varscan2
- MRPL38 | c.1086C>T p.P362= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs186214172; called by muse, varscan2
- MTA3 | c.1242A>T p.G414= | Silent (SNP) | VAF 6/144 reads (4%) | catalogued as COSV100780939; called by muse, mutect2
- MTIF2 | c.927G>T p.V309= | Silent (SNP) | VAF 30/381 reads (8%) | called by muse, mutect2
- MYH14 | c.2601G>A p.Q867= | Silent (SNP) | VAF 22/237 reads (9%) | called by muse, mutect2, varscan2
- MZF1 | c.483A>G p.P161= | Silent (SNP) | VAF 34/189 reads (18%) | called by muse, mutect2, varscan2
- NCKAP5 | c.5328C>T p.S1776= | Silent (SNP) | VAF 10/252 reads (4%) | called by muse, mutect2
- NLRP5 | c.2064C>T p.F688= | Silent (SNP) | VAF 43/235 reads (18%) | called by muse, mutect2, varscan2
- NPC1L1 | c.1707C>A p.A569= | Silent (SNP) | VAF 47/271 reads (17%) | called by muse, mutect2, varscan2
- NPHS1 | c.1296G>T p.S432= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as rs766646699, COSV62288188; called by muse, mutect2, varscan2
- NPHS2 | c.75G>A p.K25= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- OR2A5 | c.630G>T p.P210= | Silent (SNP) | VAF 86/524 reads (16%) | catalogued as rs372854651; called by muse, mutect2, varscan2
- OR51E1 | c.795C>A p.R265= | Silent (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- OR5AP2 | c.636T>A p.I212= | Silent (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- OR5K1 | c.546T>C p.L182= | Silent (SNP) | VAF 33/292 reads (11%) | called by muse, mutect2, varscan2
- OR5M8 | c.456G>T p.A152= | Silent (SNP) | VAF 19/348 reads (5%) | catalogued as COSV59116388; called by muse, mutect2
- OTOF | c.1233C>T p.P411= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs1013594965; called by muse, mutect2, varscan2
- PBRM1 | c.3765G>T p.L1255= (on ENST00000296302 / NM_001366071.2; = p.L1230= on NM_018313.5) | Silent (SNP) | VAF 28/273 reads (10%) | called by muse, mutect2, varscan2
- PCDH17 | c.1413G>T p.R471= | Silent (SNP) | VAF 50/246 reads (20%) | called by muse, mutect2, varscan2
- PCDH19 | c.1887C>T p.T629= | Silent (SNP) | VAF 83/321 reads (26%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1908C>A p.V636= | Silent (SNP) | VAF 31/177 reads (18%) | catalogued as COSV65372879; called by muse, mutect2, varscan2
- PCDHB9 | c.1515C>A p.S505= | Silent (SNP) | VAF 75/508 reads (15%) | called by muse, mutect2, varscan2
- PDGFRA | c.414C>A p.V138= | Silent (SNP) | VAF 43/423 reads (10%) | catalogued as COSV99957926; called by muse, mutect2, varscan2
- PDPR | c.2511G>T p.R837= | Silent (SNP) | VAF 30/622 reads (5%) | called by muse, mutect2
- PIK3C2B | c.3327G>T p.G1109= | Silent (SNP) | VAF 6/148 reads (4%) | called by muse, mutect2
- PLXNA4 | c.3384G>T p.L1128= | Silent (SNP) | VAF 80/488 reads (16%) | called by muse, mutect2, varscan2
- PMFBP1 | c.2943C>G p.T981= (on ENST00000537465; = p.T976= on NM_031293.3) | Silent (SNP) | VAF 23/250 reads (9%) | called by muse, mutect2, varscan2
- POC1A | c.309A>T p.T103= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- POLE | c.1599G>T p.V533= | Silent (SNP) | VAF 30/326 reads (9%) | called by muse, mutect2
- PSG3 | c.51G>A p.G17= | Silent (SNP) | VAF 73/380 reads (19%) | called by muse, mutect2, varscan2
- PTGS1 | c.1698G>C p.L566= | Silent (SNP) | VAF 31/247 reads (13%) | called by muse, mutect2, varscan2
- PTPRO | c.2361T>A p.T787= | Silent (SNP) | VAF 53/471 reads (11%) | called by muse, mutect2, varscan2
- PTPRT | c.2760C>T p.N920= | Silent (SNP) | VAF 39/260 reads (15%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.2394T>A p.P798= | Silent (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- PZP | c.3684C>A p.A1228= | Silent (SNP) | VAF 37/486 reads (8%) | catalogued as COSV99735617; called by muse, mutect2
- RAD21L1 | c.933A>T p.I311= | Silent (SNP) | VAF 47/381 reads (12%) | called by muse, mutect2, varscan2
- RAPGEF4 | c.2736A>T p.T912= | Silent (SNP) | VAF 28/320 reads (9%) | called by muse, mutect2
- RELN | c.5091C>A p.V1697= | Silent (SNP) | VAF 75/479 reads (16%) | called by muse, mutect2, varscan2
- RGS9BP | c.561C>T p.S187= | Silent (SNP) | VAF 14/96 reads (15%) | called by muse, mutect2, varscan2
- RP1L1 | c.2280C>A p.A760= | Silent (SNP) | VAF 12/127 reads (9%) | called by muse, mutect2
- RPAP3 | c.1395A>G p.L465= | Silent (SNP) | VAF 51/324 reads (16%) | called by muse, mutect2, varscan2
- RSRP1 | c.345C>G p.S115= | Silent (SNP) | VAF 9/152 reads (6%) | called by muse, mutect2
- RTL1 | c.3897C>T p.I1299= | Silent (SNP) | VAF 25/224 reads (11%) | catalogued as rs1292555623; called by muse, varscan2
- RYR1 | c.14895C>T p.G4965= | Silent (SNP) | VAF 41/352 reads (12%) | catalogued as rs767336367; called by muse, mutect2, varscan2
- SCN7A | c.1042C>A p.R348= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs867820941, COSV69272216; called by muse, mutect2
- SEMA3B | c.1443G>C p.V481= | Silent (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- SETD5 | c.2832G>T p.L944= | Silent (SNP) | VAF 38/288 reads (13%) | called by muse, mutect2, varscan2
- SLC13A1 | c.1752G>T p.S584= | Silent (SNP) | VAF 27/208 reads (13%) | catalogued as rs150844958, COSV52012990; called by muse, mutect2, varscan2
- SLC24A4 | c.403C>T p.L135= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- SLC6A5 | c.279T>A p.A93= | Silent (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- SLC6A5 | c.2268G>C p.P756= | Silent (SNP) | VAF 32/285 reads (11%) | called by muse, mutect2, varscan2
- SLC9A4 | c.651A>G p.E217= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- SLITRK2 | c.1476G>A p.G492= | Silent (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- SPACA3 | c.240C>T p.C80= | Silent (SNP) | VAF 51/321 reads (16%) | catalogued as rs1244186512; called by muse, mutect2, varscan2
- SRCIN1 | c.2208G>T p.R736= (on ENST00000621492; = p.R702= on NM_025248.3) | Silent (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1407C>T p.H469= | Silent (SNP) | VAF 18/228 reads (8%) | catalogued as rs1313384342; called by muse, mutect2
- TBC1D31 | c.1098T>C p.L366= | Silent (SNP) | VAF 56/237 reads (24%) | called by muse, mutect2, varscan2
- TECPR2 | c.1038G>A p.R346= | Silent (SNP) | VAF 41/225 reads (18%) | catalogued as rs759910087; called by muse, mutect2, varscan2
- TENT4A | c.1149A>T p.V383= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- THSD7A | c.591G>C p.V197= | Silent (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- TMC6 | c.207G>T p.R69= | Silent (SNP) | VAF 32/313 reads (10%) | called by muse, mutect2, varscan2
- TMEM135 | c.165G>T p.R55= | Silent (SNP) | VAF 21/289 reads (7%) | called by muse, mutect2
- TOGARAM2 | c.768C>T p.S256= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as rs746220487, COSV65421280; called by mutect2, varscan2
- TPSG1 | c.382C>T p.L128= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV52357753; called by muse, mutect2, varscan2
- TRIM42 | c.876C>T p.H292= | Silent (SNP) | VAF 52/426 reads (12%) | called by muse, mutect2, varscan2
- TRPM1 | c.4533C>T p.V1511= | Silent (SNP) | VAF 44/286 reads (15%) | catalogued as rs1468622803, COSV56640210; called by muse, mutect2, varscan2
- TRPM1 | c.1665G>A p.R555= | Silent (SNP) | VAF 48/448 reads (11%) | called by muse, mutect2
- TSPAN2 | c.216G>T p.V72= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- TTBK1 | c.2421G>T p.T807= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.4371A>T p.P1457= (on ENST00000591111; = p.P1411= on NM_003319.4) | Silent (SNP) | VAF 36/281 reads (13%) | catalogued as COSV60387415; called by muse, mutect2, varscan2
- ULK2 | c.1368A>G p.P456= | Silent (SNP) | VAF 22/193 reads (11%) | catalogued as rs1486226625; called by muse, mutect2, varscan2
- WDR35 | c.3213A>T p.L1071= (on ENST00000345530 / NM_001006657.2; = p.L1060= on NM_020779.4) | Silent (SNP) | VAF 16/217 reads (7%) | called by muse, mutect2
- ZBP1 | c.828C>A p.G276= | Silent (SNP) | VAF 26/200 reads (13%) | catalogued as COSV59063607; called by muse, mutect2, varscan2
- ZFHX2 | c.4821C>A p.T1607= | Silent (SNP) | VAF 30/159 reads (19%) | catalogued as rs979609553; called by muse, mutect2, varscan2
- ZNF189 | c.1020C>G p.G340= | Silent (SNP) | VAF 20/153 reads (13%) | called by muse, mutect2, varscan2
- AC002511.3 | n.247G>T | RNA (SNP) | VAF 35/231 reads (15%) | called by muse, mutect2, varscan2
- AC005863.1 | n.459C>A | RNA (SNP) | VAF 34/262 reads (13%) | called by muse, mutect2, varscan2
- AC006288.1 | n.205C>G | RNA (SNP) | VAF 16/118 reads (14%) | called by muse, mutect2, varscan2
- ACR | c.565+155C>A | Intron (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- ADGRA1 | c.4-3975G>T | Intron (SNP) | VAF 47/400 reads (12%) | called by muse, mutect2, varscan2
- ADRA1A | c.1270-8323C>A | Intron (SNP) | VAF 9/164 reads (5%) | called by muse, mutect2
- AKR1B1P6 | n.31C>G | RNA (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- AKT2 | c.*218G>A | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73849869 G>C | 5'Flank (SNP) | VAF 17/40 reads (43%) | catalogued as rs2855089; called by muse, mutect2, varscan2
- C11orf40 | n.223C>A | RNA (SNP) | VAF 15/283 reads (5%) | called by muse, mutect2
- CASR | c.*4G>A | 3'UTR (SNP) | VAF 20/184 reads (11%) | catalogued as rs1165464823, COSV99948543; called by muse, mutect2, varscan2
- CD8A | c.*476G>T | 3'UTR (SNP) | VAF 12/208 reads (6%) | catalogued as COSV52156931; called by muse, mutect2
- CDHR2 | c.2807-11C>A | Intron (SNP) | VAF 24/115 reads (21%) | called by muse, mutect2, varscan2
- CELF4 | c.1165+28C>T | Intron (SNP) | VAF 17/148 reads (11%) | called by muse, mutect2, varscan2
- CELF4 | c.658-37T>A | Intron (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- CLUHP11 | n.750C>G | RNA (SNP) | VAF 12/266 reads (5%) | called by muse, mutect2
- CNGA4 | c.1267+88C>A | Intron (SNP) | VAF 3/17 reads (18%) | called by muse, mutect2
- CPA1 | c.696+25G>T | Intron (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- CXCL12 | c.*354C>T | 3'UTR (SNP) | VAF 47/297 reads (16%) | called by muse, mutect2, varscan2
- CYB5R2 | c.659-333A>G | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, mutect2
- CYP26C1 | c.-64G>T | 5'UTR (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- DERL3 | c.327+198A>T | Intron (SNP) | VAF 5/44 reads (11%) | called by muse, varscan2
- DHRS4L2 | c.666-1507C>A | Intron (SNP) | VAF 24/156 reads (15%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.13516-19G>T | Intron (SNP) | VAF 38/288 reads (13%) | called by muse, mutect2, varscan2
- EXOC3L4 | chr14:103110479 del C | 3'Flank (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- FAM53A | c.*5G>T | 3'UTR (SNP) | VAF 35/206 reads (17%) | called by muse, mutect2, varscan2
- FEZ1 | chr11:125496611 G>A | 5'Flank (SNP) | VAF 26/128 reads (20%) | called by muse, mutect2, varscan2
- FOXP2 | c.*3189G>T | 3'UTR (SNP) | VAF 20/125 reads (16%) | called by muse, mutect2, varscan2
- GLE1 | c.*8C>G | 3'UTR (SNP) | VAF 35/293 reads (12%) | called by muse, mutect2, varscan2
- GNAS | chr20:58889185 C>A | 5'Flank (SNP) | VAF 18/111 reads (16%) | called by muse, mutect2, varscan2
- GRM7 | c.519+94701C>A | Intron (SNP) | VAF 29/294 reads (10%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1012T>C | RNA (SNP) | VAF 45/345 reads (13%) | called by muse, mutect2, varscan2
- GUSBP10 | n.237A>T | RNA (SNP) | VAF 25/165 reads (15%) | called by muse, mutect2, varscan2
- GVINP1 | n.5213G>T | RNA (SNP) | VAF 22/140 reads (16%) | called by muse, mutect2, varscan2
- HBE1 | c.-267+183G>T | Intron (SNP) | VAF 17/240 reads (7%) | called by muse, mutect2
- HSD17B1 | chr17:42552901 del C | 5'Flank (DEL) | VAF 15/103 reads (15%) | called by mutect2, pindel, varscan2
- HYKK | c.477+3535G>C | Intron (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- IFI30 | c.*2G>T | 3'UTR (SNP) | VAF 32/203 reads (16%) | called by mutect2, varscan2
- IGFN1 | c.1242-1090C>A | Intron (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
- IGHEP1 | n.548C>A | RNA (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2, varscan2
- KCNK17 | c.689-665C>A | Intron (SNP) | VAF 34/106 reads (32%) | called by muse, varscan2
- KDM2A | c.*518C>T | 3'UTR (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- KRT6A | c.1203+21G>T | Intron (SNP) | VAF 54/552 reads (10%) | called by muse, mutect2
- LBX1 | chr10:101232386 T>A | 5'Flank (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- LDLR | c.67+1141C>A | Intron (SNP) | VAF 14/101 reads (14%) | called by muse, mutect2, varscan2
- LEPR | c.-158G>T | 5'UTR (SNP) | VAF 24/114 reads (21%) | called by muse, mutect2, varscan2
- LINC02412 | n.811C>A | RNA (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- LINC02610 | n.520G>T | RNA (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- LINC02876 | n.250A>T | RNA (SNP) | VAF 50/418 reads (12%) | called by muse, mutect2, varscan2
- MAP2 | c.4585-1098G>T | Intron (SNP) | VAF 10/167 reads (6%) | called by muse, mutect2
- MIR329-1 | n.56C>A | RNA (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- MIR892A | n.8C>A | RNA (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- NHS | c.853-2074C>T | Intron (SNP) | VAF 29/166 reads (17%) | called by muse, mutect2, varscan2
- NOSTRIN | c.114-6355A>T | Intron (SNP) | VAF 15/111 reads (14%) | called by muse, mutect2, varscan2
- OR2L1P | n.422G>T | RNA (SNP) | VAF 36/413 reads (9%) | catalogued as rs748510432; called by muse, mutect2
- OTOF | c.2215-54G>T | Intron (SNP) | VAF 9/144 reads (6%) | catalogued as COSV55501087; called by muse, mutect2
- PARP14 | c.4941+425A>T | Intron (SNP) | VAF 41/370 reads (11%) | called by muse, mutect2, varscan2
- PFKFB3 | c.-35C>G | 5'UTR (SNP) | VAF 23/159 reads (14%) | called by muse, mutect2, varscan2
- PKD1L2 | n.2687C>A | RNA (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- PNPLA3 | c.*353G>A | 3'UTR (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- PRSS12 | c.1489+38A>T | Intron (SNP) | VAF 30/269 reads (11%) | called by muse, mutect2, varscan2
- PSG5 | c.431-2840G>T | Intron (SNP) | VAF 78/737 reads (11%) | called by muse, mutect2, varscan2
- RN7SL211P | chr2:64904432 C>T | 3'Flank (SNP) | VAF 36/171 reads (21%) | called by muse, mutect2, varscan2
- RNF103 | c.-920C>T | 5'UTR (SNP) | VAF 16/89 reads (18%) | catalogued as rs761133401, COSV52893826; called by muse, mutect2, varscan2
- SCN2A | c.606-163A>T | Intron (SNP) | VAF 61/472 reads (13%) | called by muse, mutect2, varscan2
21 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 21 other) are not listed here.
